Gene-level copy-number profile of tumor specimen TCGA-EE-A182-06A from TCGA case TCGA-EE-A182, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 85.2 years (31,124 days).
Specimen TCGA-EE-A182-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.7c8ec370-25a8-43d3-940f-1d1a331d70e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A182-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b0844e62-399f-415e-a355-ba5961c7d6a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 6,978; copy number 2: 48,234; copy number 3: 3,775; copy number 4: 275; copy number 5: 537.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A182-06A-11D-A194-01): tumor purity 0.62, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,044,883–197,201,293, 15 genes (within-gene range 0–1): LINC01724, KCNT2, MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B, ASPM, SEPTIN14P12, ZBTB41.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 537 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,930,040–157,417,259, 256 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:200,027,614–200,177,420, 1 gene, copy number 5 (within-gene range 3–5): NR5A2.
- chr1:200,147,531–201,429,866, 32 genes, copy number 5: AC096633.1, CCNQP1, LINC00862, AC097065.2, AC097065.1, AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, AC119427.1, TNNI1, AC096677.3.
- chr1:201,622,885–201,826,969, 1 gene, copy number 5 (within-gene range 3–5): NAV1.
- chr1:201,688,259–205,285,632, 125 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:206,470,476–206,612,465, 8 genes, copy number 5: IKBKE, MIR6769B, C1orf147, AC244034.2, RASSF5, AC244034.1, AC244034.3, EIF2D.
- chr1:222,452,738–223,864,851, 31 genes, copy number 5: AL513314.1, CICP13, AL513314.2, RNU6-791P, AL592148.2, HHIPL2, TAF1A, TAF1A-AS1, MIA3, AL592148.1, AL592148.3, AIDA, BROX, FAM177B, AL392172.1, DISP1, NDUFB1P2, AL929091.1, TLR5, AL359979.2, AL359979.1, SUSD4, RNU4-57P, CCDC185, CAPN8, SNRPEP10, RNU6-1248P, CAPN2, TP53BP2, PHBP11, ACTBP11.
- chr1:243,917,402–247,331,846, 83 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,978. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
